Somatic mutation profile of tumor specimen MP2PRT-PASZJD-TMP1-A (aliquot MP2PRT-PASZJD-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASZJD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (902 days).
Specimen MP2PRT-PASZJD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28002ea3-de23-490b-8ae5-b423fa805506.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASZJD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASZJD-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b6fa0dc-dc8a-4590-bb67-1131205832b5

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 13/113 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- CASZ1 | c.4304G>A p.R1435Q | Missense Mutation (SNP) | VAF 240/531 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.988); catalogued as rs752733658; called by muse, mutect2, varscan2
- DNAH9 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 185/885 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs199639850; called by muse, mutect2, varscan2
- GABRD | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 172/584 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1002172902, COSV101059502; called by muse, mutect2, varscan2
- HMCN2 | c.13220G>A p.R4407Q | Missense Mutation (SNP) | VAF 154/668 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776171443; called by muse, varscan2
- MORC1 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777865307, COSV51719668; called by muse, mutect2, varscan2
- MSH2 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as rs763459034, COSV51875561; called by muse, mutect2
- PTPRM | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 105/521 reads (20%) | catalogued as rs773093730, COSV59871233; called by muse, mutect2, varscan2
- DDX21 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- FLT3 | c.1780_1790delinsCC p.F594_Y597delinsP | In Frame Del (DEL) | VAF 53/226 reads (23%) | called by pindel, varscan2*
- GAS2 | c.185A>G p.D62G | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GPATCH1 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- HROB | c.1320T>A p.S440R | Missense Mutation (SNP) | VAF 80/418 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ANKRD11 | c.5175G>A p.P1725= | Silent (SNP) | VAF 185/651 reads (28%) | catalogued as rs760434985; called by muse, mutect2, varscan2
- BAG4 | c.1158G>C p.V386= | Silent (SNP) | VAF 11/217 reads (5%) | called by muse, mutect2
- FBLN2 | c.1917C>T p.D639= | Silent (SNP) | VAF 109/359 reads (30%) | catalogued as rs200610728, COSV55485106; called by muse, mutect2, varscan2
- VILL | c.2328G>A p.S776= | Silent (SNP) | VAF 379/762 reads (50%) | catalogued as rs778015763; called by muse, mutect2, varscan2
- CR1 | c.487+12247G>T | Intron (SNP) | VAF 42/224 reads (19%) | catalogued as COSV100887424, COSV65461032; called by mutect2, varscan2
